Gene-level copy-number profile of tumor specimen TCGA-29-1769-01A from TCGA case TCGA-29-1769, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 40.4 years (14,754 days).
Specimen TCGA-29-1769-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.4ca2c9fb-cff8-45b6-8a58-5b5926996519.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1769-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0cdfbf1b-b665-47c6-a1df-fe9b28fd5cf6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 377; copy number 2: 18,575; copy number 3: 8,338; copy number 4: 18,921; copy number 5: 6,539; copy number 6: 4,354; copy number 7: 1,330; copy number 8: 202; copy number 9: 248; copy number 10: 461; copy number 11: 273; copy number 12: 52; copy number 14: 137.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1769-01A-01D-0577-01): tumor purity 0.88, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:67,375,133–67,516,720, 4 genes: AC091042.1, AC110597.1, DSEL, AC110597.3.
- chr18:67,602,692–67,603,022, 1 gene: AC022662.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,171 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:174,072,447–183,215,414, 175 genes, copy number 9 (broad region; genes not listed).
- chr2:183,260,642–183,261,046, 1 gene, copy number 9: LIN28AP1.
- chr3:105,366,909–122,662,438, 281 genes, copy number 10–14 (within-gene range 4–14) (broad region; genes not listed).
- chr3:159,711,852–179,267,002, 240 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr4:2,934,882–3,890,249, 23 genes, copy number 12: NOP14-AS1, NOP14, GRK4, HTT, RNU6-204P, HTT-AS, AL390065.2, AL390065.1, MSANTD1, RGS12, AL645949.1, AL645949.2, HGFAC, AL590235.2, DOK7, LRPAP1, AL590235.1, LINC00955, AL121796.1, LINC02171, LINC02600, ADRA2C, OR7E163P.
- chr4:5,897,373–6,200,555, 1 gene, copy number 10 (within-gene range 5–10): C4orf50.
- chr4:6,026,199–8,358,338, 49 genes, copy number 10: JAKMIP1, AC092442.1, AC113615.2, LINC02495, AC113615.1, AC116317.2, WFS1, AC116317.1, PPP2R2C, MAN2B2, MRFAP1, LINC02482, AC093323.4, AC093323.1, LINC02481, AC093323.2, S100P, AC093323.3, MRFAP1L1, BLOC1S4, AC106045.1, KIAA0232, TBC1D14, AC097382.3, AC097382.1, RN7SKP292, AC097382.2, CCDC96, TADA2B, GRPEL1, LINC02447, RN7SKP36, SORCS2, MIR4798, PSAPL1, MIR4274, AFAP1-AS1, AFAP1, AC112254.1, AC097381.1, ABLIM2, MIR95, AC097381.3, AC097381.2, GMPSP1, SH3TC1, HTRA3, LINC02517, AC104825.1.
- chr11:88,504,576–89,065,945, 1 gene, copy number 9 (within-gene range 5–9): GRM5.
- chr11:89,177,875–91,116,555, 71 genes, copy number 9 (broad region; genes not listed).
- chr12:9,664,969–13,982,002, 143 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr12:14,503,661–26,833,194, 183 genes, copy number 10–14 (within-gene range 5–14) (broad region; genes not listed).
- chr12:130,024,493–130,048,376, 3 genes, copy number 11: AC055717.2, LINC02418, AC135388.1.

Autosomal genes at a single copy (total copy number 1): 377. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
